Gene-level copy-number profile of tumor specimen CUPP-B395-TTM1-A from CCG case CUPP-B395, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 65.6 years (23,950 days).
Specimen CUPP-B395-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a07a7b4e-fa45-4c01-bcee-41aa7fa5bc6d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B395-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/30340b70-e32e-4f01-973c-dbdc027a72e1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 17,540; copy number 2: 34,974; copy number 3: 5,323; copy number 4: 230; copy number 5: 185; copy number 6: 80; copy number 15: 1; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,100,236–90,100,738, 1 gene: IGKV1D-16.
- chr7:63,768,257–63,771,047, 1 gene: CICP24.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:21,802,636–23,438,700, 20 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr15:25,176,832–25,225,284, 27 genes (within-gene range 0–1): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:31,060,843–31,074,240, 2 genes (within-gene range 0–2): ZNF668, AC135050.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 267 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:92,151–189,972, 2 genes, copy number 5: PLEKHG4B, Y_RNA.
- chr5:9,035,033–9,546,075, 1 gene, copy number 5 (within-gene range 2–5): SEMA5A.
- chr5:9,363,275–12,297,504, 55 genes, copy number 5: AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P.
- chr7:63,632,608–63,636,617, 1 gene, copy number 22: AC006015.1.
- chr14:19,847,367–21,712,843, 127 genes, copy number 5 (broad region; genes not listed).
- chr14:32,879,246–36,679,362, 79 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr21:43,414,483–43,427,131, 1 gene, copy number 6: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 15 (within-gene range 4–15): LINC00313.

Autosomal genes at a single copy (total copy number 1): 15,209. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
